Gene-level copy-number profile of tumor specimen TCGA-AA-3712-01A from TCGA case TCGA-AA-3712, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage III; Age at diagnosis: 65.2 years (23,831 days).
Specimen TCGA-AA-3712-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.362e1b41-9605-4360-93e0-e5b859fcb65b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3712-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7f92e07e-585a-40fa-a502-914dc2decb4f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 775; copy number 2: 14,923; copy number 3: 26,422; copy number 4: 12,725; copy number 5: 3,292; copy number 6: 161; copy number 7: 1,467; copy number 9: 14; copy number 14: 3; copy number 20: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3712-01A-21D-1717-01): tumor purity 0.65, ploidy 3.15, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,520 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:20,221,962–20,773,961, 13 genes, copy number 7: GJB6, CRYL1, MIR4499, AL590096.1, IFT88, SLC35E1P1, RNU2-7P, AL161772.1, IL17D, AL512652.2, EEF1AKMT1, RANP8, AL512652.1.
- chr13:26,044,597–28,138,193, 53 genes, copy number 9–20: SHISA2, LINC00415, ATP8A2P3, PRUNEP1, RNF6, AL138966.2, AL138966.1, THAP12P6, CDK8, AL159159.1, AL353789.1, WASF3, RPS3AP44, WASF3-AS1, AL159978.1, GPR12, FGFR1OP2P1, AL160035.1, RPS21P8, RPS20P32, USP12, AL158062.1, USP12-AS1, USP12-AS2, LINC02340, LINC00412, RPL21, SNORD102, SNORA27, RASL11A, RNU6-70P, LINC01079, RNY1P1, GTF3A, MTIF3, RNU6-63P, LNX2, POLR1D, AL136439.1, NPM1P4, GSX1, PLUT, RNU6-73P, PDX1, ATP5F1EP2, LINC00543, CDX2, URAD, RN7SL272P, FLT3, KATNBL1P1, CHCHD2P8, PAN3-AS1.
- chr20:87,250–16,053,197, 291 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr20:15,280,764–64,313,132, 1,163 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
